CCDI case PBCMZJ — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Other and ill-defined digestive organs.
https://portal.gdc.cancer.gov/cases/61bec554-3182-413c-91d0-f2ef46691870

Demographics
Sex at birth: female; Race: black or african american.

Diagnoses (1)
1. Embryonal sarcoma: ICD-O-3 morphology code: 8991/3; Tissue or organ of origin: Liver; Age at diagnosis: 12.4 years (4,534 days).

Biospecimens (2 samples)
- Sample 0DVKG7: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DVKG9: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
